Gene-level copy-number profile of tumor specimen HCM-CSHL-0057-C18-01B from HCMI case HCM-CSHL-0057-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: GB; Age at diagnosis: 68.4 years (24,973 days).
Specimen HCM-CSHL-0057-C18-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 809c2fc5-bccd-4d8e-9bb1-abaa9d0f6a1a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0057-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/27ebe56e-50b6-4132-9ebb-e4d5a9831f19

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 510; copy number 2: 19; copy number 3: 137; copy number 4: 30,890; copy number 5: 2,977; copy number 6: 14,726; copy number 7: 2,271; copy number 8: 5,403; copy number 9: 510; copy number 10: 1,345; copy number 11: 3; copy number 12: 1; copy number 13: 1; copy number 14: 2; copy number 15: 6; copy number 16: 33; copy number 30: 16; copy number 35: 46; copy number 57: 17; copy number 83: 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:97,737,894–97,738,913, 1 gene: AC112203.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,981 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–180,982,611, 3 genes, copy number 11: AC091874.2, AC091874.1, ARPP19P1.
- chr8:99,873,200–145,066,685, 691 genes, copy number 9–10 (within-gene range 6–10) (broad region; genes not listed).
- chr13:72,567,213–73,995,056, 22 genes, copy number 9: AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392, KLF12, AL138713.1, AL159972.1.
- chr16:29,038,655–31,649,222, 215 genes, copy number 10 (broad region; genes not listed).
- chr16:46,469,341–53,703,938, 176 genes, copy number 9–57 (broad region; genes not listed).
- chr20:22,371,216–22,471,557, 1 gene, copy number 13: AL133464.1.
- chr20:30,214,765–37,406,050, 233 genes, copy number 10 (broad region; genes not listed).
- chr20:37,492,472–64,327,972, 636 genes, copy number 10 (broad region; genes not listed).
- chr21:43,414,483–43,479,534, 4 genes, copy number 12–83: SIK1, LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 8. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
